Gene-level copy-number profile of tumor specimen AP-8MWD-YD from APOLLO case AP-8MWD, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3.
Specimen AP-8MWD-YD: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 770816a5-c99c-4fa0-a21a-979aa7a3f618.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-8MWD-LR (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/49eb8f81-2296-4870-9ef9-3f866f5e8f9d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 97; copy number 2: 7,929; copy number 3: 22,095; copy number 4: 20,232; copy number 5: 5,084; copy number 6: 3,024; copy number 7: 394; copy number 8: 8; copy number 9: 39.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 441 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,533,603–155,859,400, 141 genes, copy number 7 (broad region; genes not listed).
- chr1:202,999,738–207,641,765, 145 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr1:244,352,635–247,577,690, 77 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr1:248,810,446–248,937,043, 8 genes, copy number 8: SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr2:88,811,186–88,861,563, 2 genes, copy number 9 (within-gene range 4–9): MALLP2, AC244205.1.
- chr2:88,857,161–89,234,912, 37 genes, copy number 9: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29.
- chr7:77,310,751–77,798,434, 7 genes, copy number 7 (within-gene range 6–7): GSAP, AC004921.1, GCNT1P5, PTPN12, APTR, RSBN1L, TMEM60.
- chr7:130,791,264–131,110,161, 1 gene, copy number 7 (within-gene range 6–7): AC016831.6.
- chr7:130,840,204–131,558,217, 15 genes, copy number 7: AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS, AC008264.2, PODXL, AC008264.1.
- chr14:105,890,084–105,896,577, 6 genes, copy number 7 (within-gene range 5–7): AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16.
- chr14:105,917,979–105,932,642, 2 genes, copy number 7 (within-gene range 5–7): FAM30A, IGHD1-1.

Autosomal genes at a single copy (total copy number 1): 97. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
